Somatic mutation profile of tumor specimen TCGA-AO-A0J9-01A (aliquot TCGA-AO-A0J9-01A-11W-A050-09) from TCGA case TCGA-AO-A0J9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 62.0 years (22,642 days).
Specimen TCGA-AO-A0J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1467a25-e3fa-4e63-b00d-13a80b01f4fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0J9-10A (Blood Derived Normal), aliquot TCGA-AO-A0J9-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ae785cc-3476-415a-9f2e-4f3bf21d8e92

The open-access MAF lists 126 somatic variants for this specimen: 93 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, Silent 30, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.4840A>T p.M1614L | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); catalogued as COSV58127167; called by muse, mutect2, varscan2
- AGGF1 | c.1612G>A p.D538N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.942); catalogued as COSV57227492; called by muse, mutect2, varscan2
- ANKRD17 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.958); catalogued as COSV58214382; called by muse, mutect2, varscan2
- ANKS1B | c.2671G>A p.E891K (on ENST00000547776 / NM_152788.4; = p.E117K on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.732); catalogued as COSV60355800; called by muse, mutect2, varscan2
- ARMC3 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV99958049; called by muse, mutect2
- ARRDC2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99716747; called by muse, mutect2
- BMX | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 12/174 reads (7%) | catalogued as COSV59592714; called by muse, mutect2
- C3 | c.3118G>C p.E1040Q | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV99836622; called by muse, mutect2
- CDH19 | c.961-1G>A p.X321_splice | Splice Site (SNP) | VAF 44/169 reads (26%) | catalogued as COSV50954124, COSV50959722; called by muse, mutect2, varscan2
- CELA3B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1398335872, COSV61402792; called by muse, mutect2, varscan2
- CHI3L2 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV63873229; called by muse, mutect2, varscan2
- CNDP2 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100159092; called by muse, mutect2
- CNST | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV63622786; called by muse, mutect2, varscan2
- COL11A2 | c.3653C>T p.S1218L (on ENST00000341947 / NM_080680.3; = p.S1111L on NM_080679.2) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs375065728; called by muse, mutect2, varscan2
- COMMD6 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs372073245; called by muse, mutect2, varscan2
- CORO1C | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.123); catalogued as COSV54593754; called by muse, mutect2, varscan2
- CPN1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV64941865; called by muse, mutect2, varscan2
- CSE1L | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53700206; called by muse, mutect2, varscan2
- CYP2A6 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 9/269 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991825, COSV99991837; called by muse, mutect2
- CYP3A7 | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV60480298, COSV60480876; called by muse, mutect2, varscan2
- DALRD3 | c.1444-1G>A p.X482_splice (on ENST00000341949 / NM_001009996.3; = p.X315_splice on NM_018114.5) | Splice Site (SNP) | VAF 10/64 reads (16%) | catalogued as COSV58243722; called by muse, mutect2, varscan2
- DDX50 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); catalogued as COSV65291617; called by muse, mutect2, varscan2
- DLGAP2 | c.2387G>T p.G796V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV70093254, COSV70099446; called by muse, mutect2, varscan2
- DNAH2 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs968120016, COSV50013131; called by muse, mutect2, varscan2
- DNM1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57848382, COSV57851712; called by muse, mutect2, varscan2
- ECM2 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV60738842; called by muse, mutect2, varscan2
- ERAP2 | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs113436741, COSV101163979, COSV65938461; called by muse, mutect2, varscan2
- FOXP2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV63481752; called by muse, mutect2, varscan2
- FUT11 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100226801; called by muse, mutect2
- GAB4 | c.542G>T p.C181F | Missense Mutation (SNP) | VAF 22/380 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101271979; called by muse, mutect2
- GABRG3 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61508804, COSV61518661; called by muse, mutect2, varscan2
- GATAD2B | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.037); catalogued as COSV100897869; called by muse, mutect2
- GPATCH4 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.13); catalogued as COSV100576933; called by muse, mutect2, varscan2
- HAUS6 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746342417, COSV65840944; called by muse, mutect2, varscan2
- HEATR5A | c.4298G>A p.R1433K | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs1260918391, COSV101119964; called by muse, mutect2
- HECTD1 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101237375; called by muse, mutect2
- IL27RA | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV54598516; called by muse, mutect2, varscan2
- KIF24 | c.3850C>T p.Q1284* | Nonsense Mutation (SNP) | VAF 8/123 reads (7%) | catalogued as COSV99903171; called by muse, mutect2
- KLHDC10 | c.643A>T p.I215F | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.943); catalogued as COSV59050015; called by muse, mutect2, varscan2
- KPNA2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV57856760, COSV57857856; called by muse, mutect2, varscan2
- KRI1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV57263364; called by muse, mutect2, varscan2
- LRRTM2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV51219395, COSV51220596; called by muse, mutect2, varscan2
- MACF1 | c.6098C>G p.S2033* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV57103605; called by muse, mutect2, varscan2
- MAST4 | c.2614G>A p.D872N (on ENST00000403625 / NM_001164664.2; = p.D683N on NM_015183.3) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55113869, COSV55127807; called by muse, mutect2, varscan2
- MRPL4 | c.172C>G p.H58D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as COSV99459976; called by muse, mutect2
- MTMR4 | c.2278G>T p.A760S | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV60198998; called by muse, mutect2, varscan2
- MYCBP2 | c.9116C>T p.P3039L (on ENST00000357337; = p.P3077L on NM_015057.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.33); catalogued as COSV100630315; called by muse, mutect2
- MYH6 | c.1000G>C p.D334H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62447573; called by muse, mutect2, varscan2
- NDFIP2 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV54526438; called by muse, mutect2, varscan2
- NEUROD6 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 89/778 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV51769333; called by muse, mutect2, varscan2
- NFASC | c.366C>G p.N122K (on ENST00000339876 / NM_001378329.1; = p.N116K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58357511; called by muse, mutect2, varscan2
- NUMB | c.1457C>T p.A486V (on ENST00000355058; = p.A475V on NM_003744.5) | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.027); catalogued as COSV53712442; called by muse, mutect2, varscan2
- OBSL1 | c.1826del p.S609Lfs*64 | Frame Shift Del (DEL) | VAF 7/47 reads (15%) | catalogued as COSV54711974; called by mutect2, pindel, varscan2
- OR14I1 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV100700480, COSV61199850; called by muse, mutect2
- PCDHB10 | c.1118G>T p.R373I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as COSV53374827; called by muse, mutect2, varscan2
- PCDHGA6 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.003); catalogued as rs865988022, COSV99537960; called by muse, mutect2
- PCLO | c.3389C>T p.S1130L | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61612500; called by muse, mutect2, varscan2
- PFKP | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 20/215 reads (9%) | catalogued as rs575893132, COSV66897806; called by muse, mutect2
- PHF3 | c.5116A>C p.K1706Q | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100013330; called by muse, mutect2
- PI4KA | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.283); catalogued as COSV55402738; called by muse, mutect2, varscan2
- PIWIL4 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV54406876; called by muse, mutect2, varscan2
- PLOD2 | c.2077C>G p.L693V | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.481); catalogued as rs1479446896, COSV99282740; called by muse, mutect2
- PLOD3 | c.275G>T p.W92L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99778006; called by muse, mutect2
- PRKDC | c.11683G>A p.E3895K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV58041058; called by muse, mutect2, varscan2
- PSG4 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV54932359, COSV54940351; called by muse, mutect2, varscan2
- RAI1 | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1567917304, COSV99884015; called by muse, mutect2
- RAPGEF6 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57239262; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RHOBTB3 | c.1726G>C p.E576Q | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as COSV66101073, COSV66101825; called by muse, mutect2, varscan2
- RNF19A | c.1756A>G p.T586A | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.251); catalogued as rs930205312, COSV61992118; called by muse, mutect2, varscan2
- RPL26 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV53447758, COSV99549481; called by muse, mutect2
- RTF2 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50127667; called by muse, mutect2, varscan2
- SCAF4 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV54583490; called by muse, mutect2, varscan2
- SLCO3A1 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV100575381; called by muse, mutect2
- SOX5 | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.842); catalogued as COSV58616335; called by muse, mutect2, varscan2
- SREK1IP1 | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV72486118; called by muse, mutect2, varscan2
- STK38L | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs746501951, COSV66520285; called by muse, mutect2, varscan2
- SYNE2 | c.12628G>A p.E4210K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59938223; called by muse, mutect2, varscan2
- TFAP2A | c.631G>A p.E211K (on ENST00000482890; = p.E203K on NM_001032280.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV60230419; called by muse, mutect2, varscan2
- THOC1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV55273573; called by muse, mutect2, varscan2
- TLN1 | c.5638G>C p.E1880Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.141); catalogued as COSV59203513; called by muse, mutect2, varscan2
- TRIP12 | c.5020C>T p.Q1674* | Nonsense Mutation (SNP) | VAF 15/261 reads (6%) | catalogued as COSV99390208; called by muse, mutect2
- TRPC4AP | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52676447; called by muse, mutect2, varscan2
- TSC22D3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV59776903; called by muse, mutect2, varscan2
- UBR5 | c.6185G>A p.R2062K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.815); catalogued as COSV55279192, COSV55280264; called by muse, mutect2, varscan2
- USPL1 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54998344; called by muse, mutect2, varscan2
- WDR59 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50932959; called by muse, mutect2, varscan2
- ZPR1 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 28/112 reads (25%) | catalogued as rs1395138572, COSV57062057; called by muse, mutect2, varscan2
- BEST3 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDH1 | c.1552del p.E518Nfs*4 | Frame Shift Del (DEL) | VAF 46/154 reads (30%) | called by mutect2, pindel, varscan2
- EDEM3 | c.618_622del p.N206Kfs*14 | Frame Shift Del (DEL) | VAF 20/185 reads (11%) | called by mutect2, pindel, varscan2
- PSRC1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- SLC4A7 | c.3566del p.P1189Lfs*5 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel
- ATP9B | c.2508G>A p.E836= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100303553; called by muse, mutect2
- CCM2L | c.360C>T p.L120= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99395156; called by muse, mutect2
- CCP110 | c.342C>T p.V114= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as COSV66816453; called by muse, mutect2, varscan2
- CHD6 | c.1383C>G p.L461= | Silent (SNP) | VAF 23/238 reads (10%) | catalogued as COSV100498240, COSV58560613; called by muse, mutect2
- CPM | c.1128G>T p.V376= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as COSV100615077; called by muse, mutect2
- CRYBG1 | c.1965T>A p.P655= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV64810264; called by muse, mutect2, varscan2
- DHRS7 | c.1019G>A p.*340= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs754712730, COSV53665186; called by muse, varscan2
- EIF3E | c.30C>T p.I10= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV55201119, COSV55202044, COSV55202459; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.402C>T p.P134= | Silent (SNP) | VAF 59/353 reads (17%) | catalogued as COSV60547826; called by muse, mutect2, varscan2
- FBN1 | c.3174C>T p.G1058= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV57308026; called by muse, mutect2, varscan2
- FEV | c.45C>T p.Y15= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99837905; called by muse, mutect2
- GOLM1 | c.909G>A p.Q303= | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as rs751632334, COSV57413503; called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2, varscan2
- IFNA13 | c.162G>A p.L54= | Silent (SNP) | VAF 12/151 reads (8%) | catalogued as COSV71924431; called by muse, mutect2, varscan2
- LRRC3B | c.270G>A p.L90= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as COSV67519871; called by muse, mutect2, varscan2
- LTBP2 | c.2140C>T p.L714= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV56204257; called by muse, mutect2, varscan2
- MIPOL1 | c.933G>A p.L311= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs376097457; called by muse, mutect2, varscan2
- NDRG4 | c.333C>T p.I111= (on ENST00000570248 / NM_001378344.1; = p.I143= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs368999440; called by muse, mutect2, varscan2
- ODF2 | c.1824G>A p.A608= (on ENST00000434106 / NM_153433.2; = p.A584= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs376502871, COSV63545604; called by muse, mutect2, varscan2
- OR10R2 | c.63C>T p.I21= | Silent (SNP) | VAF 84/902 reads (9%) | catalogued as COSV63768934; called by muse, mutect2
- OSBPL9 | c.1665C>G p.L555= | Silent (SNP) | VAF 61/334 reads (18%) | catalogued as rs377147799; called by muse, mutect2, varscan2
- PHC3 | c.2913G>A p.L971= (on ENST00000494943 / NM_001308116.2; = p.L983= on NM_024947.4) | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs376426899; called by muse, mutect2, varscan2
- PPM1E | c.1665G>A p.L555= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV100376220; called by muse, mutect2
- SEL1L | c.1521G>A p.L507= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV60918696; called by muse, mutect2, varscan2
- SEMA3B | c.696G>A p.P232= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV60350796; called by muse, mutect2, varscan2
- SPTBN1 | c.4875G>A p.Q1625= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV61684924; called by muse, mutect2, varscan2
- TJP1 | c.4248G>A p.E1416= | Silent (SNP) | VAF 96/338 reads (28%) | catalogued as COSV62038967; called by muse, mutect2, varscan2
- TMOD3 | c.217C>T p.L73= | Silent (SNP) | VAF 171/313 reads (55%) | catalogued as COSV57941694, COSV57943666; called by muse, mutect2, varscan2
- UBQLN1 | c.516G>A p.Q172= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV57406586; called by muse, mutect2, varscan2
- ZNF486 | c.738C>T p.V246= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV58717104; called by muse, mutect2, varscan2
- DENND10P1 | n.298C>T | RNA (SNP) | VAF 64/243 reads (26%) | catalogued as rs1014180852; called by muse, mutect2, varscan2
- GLOD4 | chr17:782690 G>A | 5'Flank (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100022450, COSV56752293; called by muse, mutect2, varscan2
- LINC00174 | n.3310C>T | RNA (SNP) | VAF 14/38 reads (37%) | catalogued as rs372581922; called by muse, mutect2, varscan2
